Somatic mutation profile of tumor specimen 0DUXPQ from CCDI case PBCLNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,181 days).
Specimen 0DUXPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f4194f9-73eb-4512-bd54-699e6d5f318e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d52df8ae-c027-42cc-a51c-04b81223e286

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs760428119, CM053750, COSV59872912; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH17 | c.8435G>A p.R2812H | Missense Mutation (SNP) | VAF 171/411 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778772093; called by muse, mutect2, varscan2
- SLC4A7 | c.2048G>T p.R683I | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as rs1358730779; called by muse, mutect2, varscan2
- CCDC171 | c.1025C>A p.A342E | Missense Mutation (SNP) | VAF 99/274 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EFCAB8 | c.3753C>T p.T1251= | Silent (SNP) | VAF 64/181 reads (35%) | called by muse, mutect2, varscan2
- LY6H | c.165C>A p.V55= | Silent (SNP) | VAF 386/898 reads (43%) | called by muse, mutect2
- SRSF5 | c.150A>G p.A50= | Silent (SNP) | VAF 78/239 reads (33%) | called by muse, mutect2, varscan2
- SNAP25 | c.-25C>T | 5'UTR (SNP) | VAF 70/142 reads (49%) | catalogued as rs889913835, COSV54776047; called by muse, mutect2, varscan2
